Gene-level copy-number profile of tumor specimen TCGA-AR-A0TY-01A from TCGA case TCGA-AR-A0TY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.3 years (19,836 days).
Specimen TCGA-AR-A0TY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1614a21e-1cc6-430a-a5da-c2a15e4542b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0TY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1080897c-64b4-441c-90b1-a77bcea680ca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 16,649; copy number 2: 39,358; copy number 3: 2,468; copy number 4: 228; copy number 5: 197; copy number 6: 208; copy number 7: 250; copy number 8: 65; copy number 13: 249.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0TY-01A-12D-A111-01): tumor purity 0.76, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 143 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:22,679,013–23,190,675, 18 genes: AC105046.1, EGR3, AC055854.1, AC105046.2, PEBP4, AC037441.1, AC037441.2, RN7SL303P, AC107959.1, RHOBTB2, TNFRSF10B, AC107959.2, AC107959.3, AC107959.4, AC107959.5, TNFRSF10C, TNFRSF10D, TNFRSF10A-AS1.
- chr9:21,135,598–22,824,213, 53 genes: AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr10:112,888,735–113,664,070, 9 genes: AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP.
- chr10:116,590,385–117,593,896, 24 genes: PNLIPRP1, PNLIPRP2, C10orf82, AC016825.1, HSPA12A, RPL5P27, ENO4, SHTN1, AC023283.1, AC012308.1, VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1, PDZD8, AC005871.2, EMX2OS, EMX2, AC005871.1, AL356419.1.
- chr17:11,598,470–12,215,267, 10 genes: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.
- chr17:29,560,547–30,108,452, 26 genes (within-gene range 0–1): ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2.
- chr17:73,067,870–73,068,288, 1 gene: ATG12P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 969 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:26,375,913–27,614,700, 26 genes, copy number 5: SDAD1P1, BNIP3L, AC011726.1, DNAJB6P2, AC011726.2, PNMA2, DPYSL2, PSME2P5, ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843.
- chr8:66,363,774–68,331,689, 40 genes, copy number 5–7: AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1.
- chr8:71,675,300–71,815,625, 3 genes, copy number 6: AC009446.1, AC104012.1, U8.
- chr8:71,841,549–71,844,468, 1 gene, copy number 6: MSC.
- chr8:74,599,775–74,823,313, 1 gene, copy number 6 (within-gene range 2–6): MIR2052HG.
- chr8:74,705,693–74,705,747, 1 gene, copy number 6: MIR2052.
- chr8:78,268,637–78,956,082, 11 genes, copy number 6 (within-gene range 3–6): PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605.
- chr8:80,265,907–80,484,481, 1 gene, copy number 6 (within-gene range 3–6): AC034114.2.
- chr8:80,405,516–81,533,275, 34 genes, copy number 6: RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12.
- chr8:83,912,713–84,164,564, 3 genes, copy number 8: AC015522.1, TPM3P3, AC012400.1.
- chr8:85,107,215–85,617,512, 14 genes, copy number 6: LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1.
- chr8:86,503,591–88,887,573, 23 genes, copy number 5: SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3.
- chr8:93,213,302–93,700,433, 1 gene, copy number 8 (within-gene range 4–8): LINC00535.
- chr8:93,441,277–94,217,303, 20 genes, copy number 8 (within-gene range 1–8): RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17.
- chr8:98,904,603–101,669,726, 78 genes, copy number 5 (broad region; genes not listed).
- chr8:101,686,547–101,872,549, 3 genes, copy number 5: AP000426.1, AP001329.1, PDCL3P2.
- chr8:106,215,763–106,981,571, 9 genes, copy number 5–6: SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1.
- chr8:107,499,773–107,506,416, 1 gene, copy number 6: AC091010.1.
- chr8:112,148,742–113,436,939, 5 genes, copy number 8 (within-gene range 1–8): RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:118,620,498–119,712,145, 18 genes, copy number 7 (within-gene range 1–7): SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153.
- chr8:123,416,726–126,329,538, 56 genes, copy number 5–7 (within-gene range 4–7): NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1.
- chr8:126,556,323–127,419,050, 1 gene, copy number 8 (within-gene range 4–8): PCAT1.
- chr8:127,072,694–128,187,101, 22 genes, copy number 8 (within-gene range 3–8): CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207.
- chr8:130,052,104–130,655,712, 7 genes, copy number 5 (within-gene range 2–5): ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr17:50,693,198–50,910,774, 15 genes, copy number 6: ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4.
- chr17:55,392,622–58,747,340, 90 genes, copy number 7 (broad region; genes not listed).
- chr17:58,785,323–58,835,994, 2 genes, copy number 7: Metazoa_SRP, RNU6-518P.
- chr17:59,331,655–73,092,712, 340 genes, copy number 5–13 (within-gene range 0–13) (broad region; genes not listed).
- chr17:73,163,035–73,312,005, 10 genes, copy number 5: POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.
- chr17:75,845,699–78,254,416, 114 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr17:79,730,943–80,149,798, 19 genes, copy number 5 (within-gene range 1–5): ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2.

Autosomal genes at a single copy (total copy number 1): 16,648. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
